Somatic mutation profile of tumor specimen TARGET-20-PASGWH-09A (aliquot TARGET-20-PASGWH-09A-01D) from TARGET case TARGET-20-PASGWH, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.4 years (5,251 days).
Specimen TARGET-20-PASGWH-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5d2d8b8f-7562-4d11-9c4e-687b8b5bc5e1.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASGWH-14A (Bone Marrow Normal), aliquot TARGET-20-PASGWH-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c5f85678-4c38-4b7c-843e-4a4b6de1c109

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RYR1 | c.325C>T p.R109W | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs118192173, CM064209, COSV62102591; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CNKSR1 | c.15G>C p.E5D | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.53); PolyPhen benign (0.308); catalogued as rs1190185440, COSV64163655; called by muse, mutect2, varscan2
- STAG2 | c.1494_1495del p.M498Ifs*2 | Frame Shift Del (DEL) | VAF 36/44 reads (82%) | called by pindel*, varscan2
